MMRF case MMRF_2587 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/36bdcbfc-c5ad-4105-920e-87b1afcc8c68

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.0 years (26,649 days); ISS stage: I; Days to last known disease status: 637 days (1.7 years); Days to last follow up: 637 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 134 days; Days to treatment end: 138 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 138 days; Days to treatment end: 138 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.196 mg/dL; Immunoglobulin G 47.3 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 3.37 µg/mL; Hemoglobin 6.57 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 9.9 g/dL; Glucose 5.34 mmol/L.
- Day 85 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.351 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.257 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 6.44 mmol/L.
- Day 173 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.133 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.207 mg/dL; Lactate Dehydrogenase 11.6 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 5.61 mmol/L.
- Day 265 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.586 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.343 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 6.49 mmol/L.
- Day 356 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.885 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.83 mmol/L.
- Day 449 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.839 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Hemoglobin 7.94 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.
- Day 533 (ECOG 0): M Protein 7.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Hemoglobin 7.87 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.72 mmol/L.
- Day 637 (ECOG 0): Hemoglobin 8.12 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -6: Weight: 62 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2587_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2587_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
